Somatic mutation profile of tumor specimen TARGET-10-PARUYH-09A (aliquot TARGET-10-PARUYH-09A-01D) from TARGET case TARGET-10-PARUYH, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.3 years (1,216 days).
Specimen TARGET-10-PARUYH-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 10ecf4c2-3c19-45e6-8a3b-182e95f787a5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARUYH-14A (Bone Marrow Normal), aliquot TARGET-10-PARUYH-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8157148c-db87-4b10-85fa-262766cc0756

The open-access MAF lists 17 somatic variants for this specimen: 10 protein-altering or splice-affecting, 4 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 4, 3'Flank 1, 3'UTR 1, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ETV6 | c.1195C>T p.R399C | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs724159945, CM150817, COSV56766387, COSV56766702, COSV56766787; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AC004922.1 | c.950C>T p.T317M | Missense Mutation (SNP) | VAF 20/164 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.463); catalogued as rs767015647, COSV53559479; called by muse, mutect2, varscan2
- BNC1 | c.427G>A p.V143I | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.53); catalogued as rs1038891510; called by muse, mutect2, varscan2
- EPHA3 | c.821G>C p.R274P | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (1); PolyPhen possibly damaging (0.447); catalogued as COSV60709306; called by muse, mutect2, varscan2
- KIR3DL3 | c.551C>T p.P184L | Missense Mutation (SNP) | VAF 5/147 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as COSV52545631, COSV99399929; called by muse, mutect2
- RAMAC | c.170G>T p.R57L | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.098); catalogued as rs757860183, COSV100417886; called by muse, mutect2, varscan2
- FAM155B | c.566G>T p.G189V | Missense Mutation (SNP) | VAF 8/127 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.226); called by muse, mutect2
- FCGBP | c.1516G>A p.D506N | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT tolerated (0.32); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- TEX15 | c.6590C>T p.T2197I (on ENST00000256246; = p.T2580I on NM_001350162.2) | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- TRAF3IP2 | c.898C>T p.Q300* | Nonsense Mutation (SNP) | VAF 14/26 reads (54%) | called by muse, mutect2, varscan2
- DCBLD1 | c.186C>T p.Y62= | Silent (SNP) | VAF 48/134 reads (36%) | called by muse, mutect2, varscan2
- NDRG2 | c.480G>A p.P160= (on ENST00000298687 / NM_001354570.1; = p.P146= on NM_016250.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as rs775221691; called by muse, mutect2, varscan2
- SLC6A20 | c.597G>A p.T199= | Silent (SNP) | VAF 32/66 reads (48%) | catalogued as rs556958366; called by muse, mutect2, varscan2
- SNED1 | c.624C>T p.L208= | Silent (SNP) | VAF 20/50 reads (40%) | catalogued as rs372363359; called by muse, mutect2, varscan2
- CPLANE1 | c.*2367C>T | 3'UTR (SNP) | VAF 10/80 reads (13%) | called by muse, mutect2, varscan2
- IGKV3D-20 | chr2:90039479 ins CC | 3'Flank (INS) | VAF 7/28 reads (25%) | called by mutect2, pindel, varscan2
- MPZL2 | c.585-59_585-58insTG | Intron (INS) | VAF 49/115 reads (43%) | called by mutect2, pindel, varscan2
